Gene-level copy-number profile of tumor specimen TCGA-CV-7418-01A from TCGA case TCGA-CV-7418, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.4 years (22,805 days).
Specimen TCGA-CV-7418-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.8f08663c-cf5a-4396-86d3-f0a5faa404f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7418-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e94dff6d-a494-454a-b262-3ddda5e00f4b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 36; copy number 2: 17,360; copy number 3: 6,192; copy number 4: 27,793; copy number 5: 1,903; copy number 6: 3,289; copy number 7: 1,280; copy number 8: 622; copy number 9: 233; copy number 10: 165; copy number 11: 248; copy number 12: 154; copy number 13: 166; copy number 14: 10; copy number 15: 1; copy number 16: 126; copy number 17: 19; copy number 18: 15; copy number 21: 14; copy number 23: 32; copy number 24: 13; copy number 25: 11; copy number 28: 12; copy number 30: 30; copy number 36: 46; copy number 37: 5; copy number 53: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7418-01A-11D-2077-01): tumor purity 0.74, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:71,289,769–71,305,853, 1 gene: FOXP1-AS1.
- chr9:5,629,025–5,776,557, 2 genes (within-gene range 0–2): RIC1, AL136980.1.
- chr9:15,553,043–16,061,663, 1 gene (within-gene range 0–2): CCDC171.
- chr9:15,776,181–16,410,990, 2 genes: RNU6-14P, C9orf92.
- chr9:16,473,188–16,476,237, 1 gene: AL449983.1.
- chr9:21,966,929–22,128,103, 7 genes (within-gene range 0–6): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr10:4,871,901–4,962,568, 2 genes: AKR1C6P, U8.
- chr13:81,689,911–81,691,072, 1 gene: PTMAP5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,313 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,052,566–148,796,325, 90 genes, copy number 10 (broad region; genes not listed).
- chr1:148,839,483–148,839,732, 1 gene, copy number 10: RN7SKP88.
- chr1:149,782,671–151,372,707, 95 genes, copy number 12 (broad region; genes not listed).
- chr1:156,806,243–168,376,876, 347 genes, copy number 13–53 (within-gene range 2–53) (broad region; genes not listed).
- chr1:184,690,237–187,686,628, 47 genes, copy number 9–24 (within-gene range 6–24): EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1.
- chr2:180,473,137–191,425,389, 137 genes, copy number 9–21 (broad region; genes not listed).
- chr3:159,282,646–159,282,734, 1 gene, copy number 15: MIR3919.
- chr3:167,239,843–174,378,005, 114 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 17: RN7SKP40.
- chr3:177,019,340–177,228,000, 1 gene, copy number 9 (within-gene range 6–9): TBL1XR1.
- chr3:177,120,691–183,812,624, 124 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr3:188,688,781–189,897,276, 8 genes, copy number 10: MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944.
- chr3:189,969,030–189,969,861, 1 gene, copy number 10: MTAPP2.
- chr4:177,309,874–183,320,777, 47 genes, copy number 11–18 (within-gene range 3–18): NEIL3, AC027627.1, AGA, AC078881.1, RNA5SP172, AC103879.1, LINC01098, LINC01099, RNU1-45P, AC095041.1, RNA5SP173, AC017087.1, AC018710.1, AC020551.1, AC021193.1, AC108169.1, AC096747.1, NDUFB5P1, AC104803.1, LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1, TENM3, AC108142.1, MIR1305, RNU2-34P, RN7SKP67, AC079226.2, AC079226.1, AC114798.1, AC079766.1, DCTD, AC019193.4, AC019193.1, CIBAR1P2, AC019193.3, AC019193.2, WWC2-AS2, WWC2, WWC2-AS1.
- chr6:46,852,522–47,369,230, 5 genes, copy number 11 (within-gene range 2–11): ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2.
- chr11:68,941,503–72,434,680, 121 genes, copy number 10–36 (within-gene range 6–36) (broad region; genes not listed).
- chr11:77,322,017–80,762,826, 52 genes, copy number 10–17 (within-gene range 8–17): PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720.
- chr18:41,955,234–49,651,160, 121 genes, copy number 11–25 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
